Somatic mutation profile of tumor specimen TCGA-QR-A6H4-01A (aliquot TCGA-QR-A6H4-01A-11D-A35D-08) from TCGA case TCGA-QR-A6H4, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 56.1 years (20,492 days).
Specimen TCGA-QR-A6H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 300c002f-8da4-4924-9620-6c1e812285ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6H4-10A (Blood Derived Normal), aliquot TCGA-QR-A6H4-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb9b0424-2689-41b6-a5cb-82741d1a986e

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 31/92 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.15124C>G p.Q5042E | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- HPS3 | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR10H2 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PRMT1 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAI1 | c.77_90del p.R26Qfs*22 | Frame Shift Del (DEL) | VAF 15/22 reads (68%) | called by mutect2, pindel, varscan2
- USP34 | c.3232A>T p.N1078Y | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MRPL13 | c.360A>C p.T120= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2039G>C | Intron (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2
